Somatic mutation profile of tumor specimen TCGA-37-5819-01A (aliquot TCGA-37-5819-01A-01D-1632-08) from TCGA case TCGA-37-5819, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65.0 years (23,726 days).
Specimen TCGA-37-5819-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33601a40-3117-49fe-a83e-2870e7a1be77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-5819-10A (Blood Derived Normal), aliquot TCGA-37-5819-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80455fb4-dd25-4e9e-9b35-c754c8ffa0cb

The open-access MAF lists 813 somatic variants for this specimen: 638 protein-altering or splice-affecting, 163 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 536, Silent 163, Nonsense Mutation 58, Frame Shift Del 18, Splice Site 15, Intron 7, Frame Shift Ins 6, Splice Region 3, RNA 3, 3'UTR 1, Translation Start Site 1, In Frame Del 1.

Variants (750 of 813; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 23/26 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260583; called by muse, mutect2, varscan2
- OSGEP | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773173317, COSV52832903; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1229314699, COSV52227249; called by muse, mutect2, varscan2
- ABCA13 | c.3498G>C p.K1166N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.928); catalogued as COSV70039628; called by muse, mutect2, varscan2
- ABCA13 | c.7043A>G p.N2348S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as COSV71292415; called by muse, mutect2, varscan2
- ABCB1 | c.2717C>A p.T906N | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958873; called by muse, mutect2, varscan2
- ABCB10 | c.1196T>G p.F399C | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60622920; called by muse, mutect2, varscan2
- ABCB5 | c.1361C>G p.A454G (on ENST00000404938 / NM_001163941.2; = p.A9G on NM_178559.6) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV51716667; called by muse, mutect2, varscan2
- ABCG4 | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 92/107 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100266644, COSV56644989, COSV56645081; called by muse, mutect2, varscan2
- ABL2 | c.2160dup p.S721Efs*9 (on ENST00000502732 / NM_007314.4; = p.S706Efs*9 on NM_005158.5) | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs771692956; called by mutect2, pindel, varscan2
- ACKR4 | c.451G>T p.G151* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV51443059; called by muse, mutect2, varscan2
- ACKR4 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV51443073; called by muse, mutect2, varscan2
- ACSL1 | c.892T>C p.S298P | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV55665299; called by muse, mutect2, varscan2
- ACTRT1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs373832447, COSV64419671; called by muse, mutect2, varscan2
- ACY3 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 93/110 reads (85%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs771927993, COSV54829400; called by muse, mutect2, varscan2
- ADAMTS12 | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61272765; called by muse, mutect2, varscan2
- ADAMTS12 | c.1729G>T p.G577* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV61272768, COSV61279289; called by muse, mutect2, varscan2
- ADAMTS16 | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV56990035, COSV57001044; called by muse, mutect2, varscan2
- ADARB2 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67231999; called by muse, mutect2, varscan2
- ADD2 | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV52467038; called by muse, mutect2, varscan2
- ADGRB3 | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.431); catalogued as COSV65411288; called by muse, mutect2, varscan2
- ADGRL3 | c.1379G>T p.G460V (on ENST00000506720 / NM_001322402.2; = p.G392V on NM_015236.6) | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72270440; called by muse, mutect2, varscan2
- ADRA2C | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs1462572210, COSV57467938; called by muse, mutect2, varscan2
- AFG3L2 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV52316502; called by muse, mutect2, varscan2
- AFM | c.179T>A p.F60Y | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.65); PolyPhen benign (0.067); catalogued as COSV56921425; called by muse, mutect2, varscan2
- AGMO | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV61120216; called by muse, varscan2
- AHCTF1 | c.4048G>T p.D1350Y (on ENST00000366508; = p.D1324Y on NM_015446.5) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58253351; called by muse, mutect2, varscan2
- AKAP6 | c.5086G>T p.E1696* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV55225828; called by muse, mutect2, varscan2
- ALX1 | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57493582; called by muse, mutect2, varscan2
- AMER3 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs368379439; called by muse, mutect2, varscan2
- ANKFN1 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV59455120, COSV59459189; called by muse, mutect2, varscan2
- ANKMY2 | c.1098G>T p.K366N | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61012347; called by muse, mutect2, varscan2
- ANKS1B | c.1856C>A p.P619H | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV100241861, COSV61346650; called by muse, mutect2
- ANP32D | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV56980791; called by muse, mutect2
- AOAH | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs781583135, COSV51747590; called by muse, varscan2
- APBB1IP | c.353C>A p.A118D | Missense Mutation (SNP) | VAF 105/134 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV63302018, COSV63303515; called by muse, mutect2, varscan2
- APOB | c.9260G>T p.W3087L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51945936; called by muse, mutect2, varscan2
- APOB | c.1133C>T p.T378I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1558574135, COSV51936732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3F | c.757T>G p.C253G | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57911471; called by muse, mutect2, varscan2
- APOH | c.945T>A p.C315* | Nonsense Mutation (SNP) | VAF 43/118 reads (36%) | catalogued as COSV52773990; called by muse, mutect2, varscan2
- ARHGAP17 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV51510548; called by muse, mutect2, varscan2
- ARHGAP36 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV52270149; called by muse, mutect2, varscan2
- ARHGAP9 | c.1630T>A p.L544M (on ENST00000393797 / NM_001319850.2; = p.L525M on NM_032496.4) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765081715, COSV57365362; called by muse, mutect2, varscan2
- ARHGEF15 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV62725942; called by muse, mutect2, varscan2
- ARHGEF26 | c.1553T>C p.V518A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62850015; called by muse, mutect2, varscan2
- ARHGEF7 | c.1660G>T p.E554* (on ENST00000375741 / NM_001113511.2; = p.E376* on NM_003899.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as COSV54548458; called by muse, mutect2, varscan2
- ARL2BP | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV54656508; called by muse, varscan2
- ARSH | c.632G>T p.W211L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.925); catalogued as COSV66963615; called by muse, mutect2, varscan2
- ASB3 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs757255593, COSV55075572; called by muse, mutect2, varscan2
- ATP11B | c.2602G>T p.G868C | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60031692; called by muse, mutect2, varscan2
- ATP1A4 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV63627166, COSV63627828; called by muse, mutect2, varscan2
- ATP5MC2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100101094, COSV58601962; called by muse, mutect2, varscan2
- ATP8A1 | c.1444A>C p.T482P | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52543522; called by muse, mutect2, varscan2
- ATP8A1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52543545; called by muse, mutect2, varscan2
- BASP1 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.906); catalogued as COSV59472462; called by muse, mutect2
- BCAN | c.2244C>G p.N748K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61258555; called by muse, mutect2
- BCAS1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65088305; called by muse, mutect2, varscan2
- BCAS3 | c.1204G>T p.G402* | Nonsense Mutation (SNP) | VAF 88/188 reads (47%) | catalogued as rs777670268, COSV66779244; called by muse, mutect2, varscan2
- BDKRB1 | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs748553489, COSV53706772; called by muse, mutect2, varscan2
- BEND6 | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV66069824; called by muse, mutect2, varscan2
- BIRC6 | c.11900T>C p.L3967P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70203689; called by muse, mutect2, varscan2
- BMP5 | c.146G>C p.R49P | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs140823469, COSV63704443, COSV63705216; called by muse, mutect2, varscan2
- BNC2 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1383583504, COSV66153624; called by muse, mutect2, varscan2
- C12orf42 | c.341T>A p.V114E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV59388045; called by muse, mutect2, varscan2
- C1orf74 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1390480092, COSV50557027; called by muse, mutect2, varscan2
- C5AR1 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs201031420, COSV61892330; called by muse, mutect2, varscan2
- C5AR1 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61893070, COSV61893253; called by muse, mutect2, varscan2
- C6orf118 | c.119A>T p.N40I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57817492; called by muse, mutect2, varscan2
- C6orf15 | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV52539515, COSV99456579; called by muse, mutect2, varscan2
- CA10 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV53363443, COSV99564179; called by muse, mutect2, varscan2
- CACNA1C | c.3943A>T p.M1315L | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59710697, COSV59753981; called by muse, mutect2, varscan2
- CACNA1S | c.3365A>T p.Y1122F | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62942241; called by muse, mutect2, varscan2
- CALN1 | c.360C>A p.D120E (on ENST00000329008 / NM_001017440.3; = p.D162E on NM_031468.4) | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as COSV61144306; called by muse, mutect2, varscan2
- CAMTA1 | c.2976G>C p.E992D | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV57918191; called by muse, mutect2, varscan2
- CASS4 | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV64387762; called by muse, mutect2, varscan2
- CAV2 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV56063693, COSV56064421; called by muse, mutect2, varscan2
- CBLB | c.2645C>G p.T882S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51433257; called by muse, mutect2, varscan2
- CBLIF | c.231C>A p.Y77* | Nonsense Mutation (SNP) | VAF 17/24 reads (71%) | catalogued as rs1221812805, COSV57239922; called by muse, mutect2, varscan2
- CCBE1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 70/132 reads (53%) | catalogued as COSV67950993; called by muse, mutect2, varscan2
- CCDC141 | c.1883T>A p.L628H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55378933; called by muse, mutect2, varscan2
- CCDC80 | c.2405G>A p.S802N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV52818905; called by muse, mutect2, varscan2
- CD22 | c.1129A>T p.T377S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.331); catalogued as COSV50061038; called by muse, mutect2, varscan2
- CD38 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56892053; called by muse, mutect2, varscan2
- CD40 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs144542285; called by muse, mutect2, varscan2
- CDH12 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as COSV66431613; called by muse, mutect2, varscan2
- CDH12 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66413307; called by muse, mutect2, varscan2
- CDH17 | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV50335594; called by muse, mutect2, varscan2
- CDH26 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54851555; called by muse, mutect2, varscan2
- CDH5 | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV58519119; called by muse, mutect2, varscan2
- CDH7 | c.1246G>C p.D416H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59891126; called by muse, mutect2, varscan2
- CDK11A | c.413G>C p.R138T (on ENST00000378633 / NM_001313896.2; = p.R148T on NM_024011.4) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62266419; called by muse, mutect2, varscan2
- CELSR2 | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54777065; called by muse, mutect2, varscan2
- CELSR3 | c.9337G>T p.E3113* | Nonsense Mutation (SNP) | VAF 32/42 reads (76%) | catalogued as COSV50996200; called by muse, varscan2
- CEP128 | c.2000A>T p.D667V | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV55385640; called by muse, mutect2, varscan2
- CEP70 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV53877352; called by muse, mutect2, varscan2
- CGB7 | c.16-1G>T p.X6_splice | Splice Site (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100654952, COSV62281866; called by muse, mutect2, varscan2
- CHD1L | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63614303, COSV63614925; called by muse, mutect2, varscan2
- CHL1 | c.2715G>T p.E905D (on ENST00000397491 / NM_001253387.1; = p.E921D on NM_006614.4) | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT tolerated (0.86); PolyPhen benign (0.028); catalogued as COSV56601032; called by muse, mutect2, varscan2
- CHRNA9 | c.1368C>G p.D456E | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59575439; called by muse, mutect2, varscan2
- CHST6 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as COSV60000893, COSV60001229; called by muse, mutect2, varscan2
- CILP | c.2383C>A p.R795S | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56026693; called by muse, mutect2, varscan2
- CLCN1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763850295, COSV58367435; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLEC14A | c.1266del p.K422Nfs*43 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as COSV60563191, COSV99046217; called by mutect2, pindel, varscan2
- CLEC3B | c.502G>C p.G168R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56110250; called by muse, mutect2
- CLEC5A | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV69396857, COSV69397801; called by muse, mutect2, varscan2
- CLIP1 | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 122/226 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56806167; called by muse, mutect2, varscan2
- CLSTN2 | c.2660C>A p.P887H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71723631; called by muse, mutect2, varscan2
- CNDP1 | c.1503A>T p.L501F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV62594765; called by muse, mutect2, varscan2
- CNTNAP2 | c.3217G>T p.D1073Y | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV62231196; called by muse, mutect2, varscan2
- CNTNAP5 | c.2733C>A p.N911K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV70501800; called by muse, mutect2, varscan2
- COL22A1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254490670, COSV57351511; called by muse, mutect2, varscan2
- COL24A1 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65310797; called by muse, mutect2, varscan2
- COL3A1 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM105921, COSV58594012; called by muse, mutect2, varscan2
- COL3A1 | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58594016; called by muse, mutect2
- COL4A6 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57873515; called by muse, mutect2, varscan2
- COL4A6 | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 17/23 reads (74%) | catalogued as COSV57873523; called by muse, mutect2, varscan2
- COL6A5 | c.6595C>A p.Q2199K (on ENST00000312481; = p.Q2195K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV55211400; called by muse, mutect2, varscan2
- COL6A6 | c.2998G>T p.D1000Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62032929; called by muse, mutect2, varscan2
- COL7A1 | c.6573+1del p.X2191_splice | Splice Site (DEL) | VAF 10/17 reads (59%) | catalogued as CS971699, CS993007; called by mutect2, pindel, varscan2
- COL9A1 | c.2668G>C p.G890R | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57889709; called by muse, mutect2, varscan2
- COPA | c.926-1G>T p.X309_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54107205; called by muse, mutect2, varscan2
- CRACR2A | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV52916574; called by muse, mutect2, varscan2
- CRACR2A | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV52916609; called by muse, mutect2, varscan2
- CRB1 | c.2777A>T p.Q926L | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV66332303; called by muse, varscan2
- CSF2RB | c.2050G>T p.G684* | Nonsense Mutation (SNP) | VAF 12/15 reads (80%) | catalogued as COSV53259885; called by muse, mutect2, varscan2
- CSMD2 | c.6017C>T p.A2006V | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.852); catalogued as COSV53942505; called by muse, mutect2
- CSMD3 | c.1640C>T p.T547M (on ENST00000297405 / NM_001363185.1; = p.T443M on NM_052900.3) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.893); catalogued as rs780453119, COSV52146436; called by muse, mutect2
- CSMD3 | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as rs1219947109, COSV52167178, COSV52266958; called by muse, mutect2, varscan2
- CTAGE1 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV101194663, COSV66944190; called by muse, mutect2, varscan2
- CXCR1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV55282572; called by muse, mutect2, varscan2
- CXXC1 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53273544; called by muse, mutect2, varscan2
- CYBB | c.1650C>A p.S550R | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV66085974; called by muse, mutect2, varscan2
- CYP11B2 | c.153G>T p.R51S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs774555520, COSV59997236; called by muse, mutect2, varscan2
- DACT1 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 41/82 reads (50%) | catalogued as COSV60022593, COSV60023625; called by muse, mutect2, varscan2
- DACT1 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV60019761, COSV60022605; called by muse, mutect2, varscan2
- DCAF13 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52573463, COSV52574495; called by muse, mutect2
- DCAF4L2 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV60480964; called by muse, mutect2, varscan2
- DCHS1 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV55040237; called by muse, mutect2, varscan2
- DEFB118 | c.83G>T p.W28L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV53621186; called by muse, mutect2, varscan2
- DENND2A | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV52049167, COSV52056219; called by muse, mutect2, varscan2
- DGKB | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV51807066; called by muse, mutect2, varscan2
- DLG2 | c.205-1G>T p.X69_splice | Splice Site (SNP) | VAF 14/18 reads (78%) | catalogued as COSV54671752; called by muse, mutect2
- DMRT1 | c.682T>C p.C228R | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66523352; called by muse, mutect2, varscan2
- DMXL1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV60718332; called by muse, mutect2, varscan2
- DNAH3 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54539920; called by muse, mutect2, varscan2
- DNM3 | c.2566C>A p.R856S (on ENST00000355305 / NM_001350206.2; = p.R850S on NM_015569.5) | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV62453819, COSV62463620; called by muse, mutect2, varscan2
- DOCK2 | c.3647G>C p.R1216T | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV56977312; called by muse, mutect2, varscan2
- DPP8 | c.1557G>T p.W519C (on ENST00000341861 / NM_001320875.2; = p.W503C on NM_017743.6) | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55681572; called by muse, mutect2, varscan2
- DPP8 | c.1556G>T p.W519L (on ENST00000341861 / NM_001320875.2; = p.W503L on NM_017743.6) | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55681591; called by muse, mutect2, varscan2
- DSC3 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV64574427; called by muse, mutect2, varscan2
- DSG4 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV57395189; called by muse, mutect2, varscan2
- DSPP | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 34/49 reads (69%) | catalogued as COSV56812867, COSV56814162; called by muse, mutect2, varscan2
- DYNC1H1 | c.11215C>T p.Q3739* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV64138241; called by muse, mutect2, varscan2
- ECHS1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63907169; called by muse, mutect2, varscan2
- EDN3 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61109306; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1070G>T p.R357I (on ENST00000361735 / NM_015935.5; = p.R271I on NM_014955.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV62283621; called by muse, mutect2, varscan2
- EIF3A | c.3182G>T p.R1061L | Missense Mutation (SNP) | VAF 90/130 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV64960545, COSV64962546; called by muse, varscan2
- ELMOD1 | c.62G>T p.W21L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.694); catalogued as COSV56194799; called by muse, mutect2, varscan2
- ELOA2 | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV55298500, COSV55304671; called by muse, mutect2, varscan2
- ENPP2 | c.1075G>A p.D359N (on ENST00000075322 / NM_001040092.3; = p.D411N on NM_006209.5) | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50028089; called by muse, mutect2, varscan2
- EPHA3 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 87/128 reads (68%) | SIFT tolerated (0.9); PolyPhen benign (0.054); catalogued as COSV60719215; called by muse, mutect2, varscan2
- EPX | c.1591C>G p.R531G | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.093); catalogued as COSV56598381, COSV56599069; called by muse, mutect2, varscan2
- ERBB4 | c.1290-1G>T p.X430_splice | Splice Site (SNP) | VAF 41/66 reads (62%) | catalogued as COSV53564823; called by muse, mutect2, varscan2
- ERBIN | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52323326; called by muse, varscan2
- ERCC8 | c.769G>T p.G257* | Nonsense Mutation (SNP) | VAF 34/50 reads (68%) | catalogued as COSV54017380; called by muse, mutect2, varscan2
- ERICH3 | c.2762C>A p.A921D | Missense Mutation (SNP) | VAF 84/126 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV58613989; called by muse, mutect2, varscan2
- ERO1B | c.675C>T p.G225= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as rs757548395, COSV59242152; called by muse, mutect2, varscan2
- ESPL1 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV57761703; called by muse, mutect2
- ESR1 | c.1117C>A p.H373N | Missense Mutation (SNP) | VAF 69/98 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV52798151; called by muse, mutect2, varscan2
- FAM169A | c.1208C>A p.A403E | Missense Mutation (SNP) | VAF 92/122 reads (75%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as COSV65846999; called by muse, mutect2, varscan2
- FAM220A | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV57627109; called by muse, mutect2
- FAM47A | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.731); catalogued as rs764031941, COSV60495676, COSV60499390; called by muse, mutect2, varscan2
- FAM71B | c.1693G>T p.V565L | Missense Mutation (SNP) | VAF 141/184 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57230186; called by muse, mutect2, varscan2
- FAM83B | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV60918875; called by muse, mutect2, varscan2
- FAT2 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV55826104; called by muse, mutect2, varscan2
- FBN1 | c.7513G>T p.G2505C | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57325797; called by muse, mutect2, varscan2
- FBXL7 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV61650241; called by muse, mutect2, varscan2
- FBXO15 | c.1318T>G p.C440G | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54047356, COSV99503543; called by muse, mutect2, varscan2
- FCF1 | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58696822; called by muse, mutect2, varscan2
- FCRL1 | c.1085C>G p.P362R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV100839801, COSV63826569; called by muse, mutect2, varscan2
- FCRL1 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as rs758178423, COSV100839667; called by muse, mutect2, varscan2
- FGA | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 89/112 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV57398986; called by muse, mutect2, varscan2
- FGD5 | c.1477G>T p.V493F | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53248535, COSV99547811; called by muse, mutect2, varscan2
- FLG | c.11634G>T p.R3878S | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs751786975, COSV64245722; called by muse, mutect2, varscan2
- FLG2 | c.4355C>G p.S1452C | Missense Mutation (SNP) | VAF 74/447 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1452513703, COSV66171335, COSV66174601; called by muse, mutect2, varscan2
- FMO3 | c.1568T>C p.L523P | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV63008125; called by muse, mutect2, varscan2
- FOXI2 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV59094785, COSV59095081; called by muse, mutect2
- FRRS1 | c.759+1G>T p.X253_splice | Splice Site (SNP) | VAF 41/58 reads (71%) | catalogued as rs1256384676, COSV54923577; called by muse, mutect2, varscan2
- FSHB | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54222533; called by muse, mutect2, varscan2
- FSIP2 | c.16523C>G p.S5508* | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as COSV100553442; called by muse, mutect2, varscan2
- FSIP2 | c.18182A>T p.Q6061L | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100553444; called by muse, mutect2, varscan2
- FXR2 | c.1786A>G p.N596D | Missense Mutation (SNP) | VAF 79/119 reads (66%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.084); catalogued as COSV51469206; called by muse, mutect2, varscan2
- FXYD5 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61569511; called by muse, mutect2, varscan2
- FYB1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs762263490, COSV60953063; called by muse, mutect2, varscan2
- FZD10 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV57474364, COSV57474947, COSV99969362; called by muse, mutect2, varscan2
- FZD3 | c.1558G>T p.V520L | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV53537055; called by muse, mutect2, varscan2
- GBP5 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV58593858; called by muse, mutect2, varscan2
- GCG | c.249G>T p.R83S | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV64960866, COSV64961946; called by muse, mutect2, varscan2
- GHSR | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as rs1039058643, COSV53840842; called by muse, mutect2, varscan2
- GK2 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.364); catalogued as rs1479818624, COSV62627913; called by muse, mutect2, varscan2
- GKN1 | c.410A>T p.N137I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV65006715; called by muse, mutect2, varscan2
- GLB1L2 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.48); PolyPhen benign (0.232); catalogued as COSV60279947; called by muse, mutect2, varscan2
- GLMN | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1265559617, COSV64861236; called by muse, mutect2, varscan2
- GLP2R | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52326159; called by muse, mutect2
- GLRA4 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 95/122 reads (78%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV65456582; called by muse, mutect2, varscan2
- GNAL | c.679G>T p.D227Y (on ENST00000269162 / NM_001142339.3; = p.D304Y on NM_182978.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99302845, COSV99304212; called by muse, mutect2, varscan2
- GOLGA4 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV62712678; called by muse, mutect2, varscan2
- GPR17 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs370252535; called by muse, mutect2, varscan2
- GPR176 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV54447202; called by muse, mutect2, varscan2
- GPR176 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371197047; called by muse, mutect2, varscan2
- GRID2 | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV56241063, COSV99943257; called by muse, mutect2, varscan2
- GRIK2 | c.2532C>A p.Y844* | Nonsense Mutation (SNP) | VAF 60/90 reads (67%) | catalogued as rs1190604743, COSV59757791; called by muse, mutect2, varscan2
- GRK1 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV59553839; called by muse, mutect2, varscan2
- GRN | c.1704G>C p.R568S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV50008246; called by muse, varscan2
- GRWD1 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV53520127; called by muse, mutect2, varscan2
- GRWD1 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV53520140; called by muse, mutect2, varscan2
- GSTZ1 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV53624123; called by muse, mutect2, varscan2
- GTF3C1 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 67/134 reads (50%) | catalogued as COSV62240615, COSV62243550; called by muse, mutect2, varscan2
- GUCY2F | c.3302G>A p.R1101K | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54306368; called by muse, varscan2
- H2BC12 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.387); catalogued as COSV63617464; called by muse, mutect2, varscan2
- HAPLN1 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907324859, COSV57150574; called by muse, mutect2
- HELB | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV56075122; called by muse, mutect2, varscan2
- HELZ | c.5365G>T p.D1789Y | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV62380001; called by muse, mutect2, varscan2
- HELZ | c.1727G>C p.C576S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1269772218, COSV62380003; called by muse, mutect2, varscan2
- HEPH | c.2081C>T p.T694I (on ENST00000343002; = p.T427I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57965158, COSV57969157; called by muse, mutect2, varscan2
- HLA-A | c.699C>A p.Y233* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs61760922, CM078303, COSV100954479, COSV65143762; called by muse, mutect2, varscan2
- HLA-A | c.893G>A p.W298* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV65143767; called by muse, mutect2, varscan2
- HMCN1 | c.5377G>T p.A1793S | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV54925867, COSV99627673; called by muse, mutect2, varscan2
- HMGCL | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 74/110 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52526895; called by muse, mutect2, varscan2
- HNRNPA0 | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59246844, COSV59247097; called by muse, mutect2, varscan2
- HSPA6 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100553920, COSV59062094; called by muse, mutect2, varscan2
- HTR3E | c.1124C>A p.T375N (on ENST00000415389 / NM_001256613.1; = p.T390N on NM_182589.2) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs904114878, COSV58948208; called by muse, mutect2, varscan2
- HTR6 | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.726); catalogued as COSV53875560; called by muse, mutect2, varscan2
- HYDIN | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV55494123; called by muse, mutect2, varscan2
- IFI16 | c.1403C>A p.P468Q | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV99856783; called by muse, mutect2, varscan2
- IFNA1 | c.532T>A p.S178T | Missense Mutation (SNP) | VAF 81/136 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV52806868; called by muse, mutect2, varscan2
- IGF2BP2 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60489588; called by muse, mutect2, varscan2
- IGSF9 | c.1609C>T p.Q537* (on ENST00000368094 / NM_001135050.2; = p.Q521* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV63641481; called by muse, mutect2
- IL17RE | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 98/121 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs200160526; called by muse, mutect2, varscan2
- IL21R | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV104402061, COSV61971812; called by muse, mutect2
- IMPG2 | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV51983037; called by muse, mutect2, varscan2
- INTS7 | c.1470G>T p.L490= | Splice Region (SNP) | VAF 28/140 reads (20%) | catalogued as COSV65344935; called by muse, mutect2, varscan2
- IPO11 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV57579638; called by muse, mutect2, varscan2
- IQCJ | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67335002; called by muse, mutect2, varscan2
- IRGC | c.867C>A p.Y289* | Nonsense Mutation (SNP) | VAF 67/163 reads (41%) | catalogued as COSV54985516; called by muse, mutect2, varscan2
- ITGAD | c.2903T>G p.F968C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54932492; called by muse, mutect2, varscan2
- ITGBL1 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66010519; called by muse, mutect2, varscan2
- ITPK1 | c.121-2A>T p.X41_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV50898321, COSV99968251; called by muse, mutect2, varscan2
- ITPR2 | c.2376G>T p.Q792H | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67273948; called by muse, mutect2, varscan2
- ITPR3 | c.1159G>T p.V387F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65413119, COSV65414352; called by muse, mutect2, varscan2
- JAK3 | c.1477A>C p.S493R | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV71686313, COSV71686956; called by muse, mutect2, varscan2
- JPH3 | c.1243A>T p.T415S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52471924; called by muse, mutect2, varscan2
- JPH3 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV52471936; called by muse, mutect2, varscan2
- KCNJ15 | c.609G>T p.R203S | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60811600; called by muse, mutect2, varscan2
- KCNT2 | c.1640C>A p.T547K | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs774233172, COSV54098387; called by muse, mutect2, varscan2
- KCNU1 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67758618; called by muse, mutect2, varscan2
- KDM5B | c.1123A>T p.R375W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52510943; called by muse, mutect2, varscan2
- KIAA0513 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs766399754, COSV50740513; called by muse, mutect2, varscan2
- KIAA1549L | c.3881G>T p.G1294V (on ENST00000321505; = p.G1591V on NM_012194.3) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55778643; called by muse, mutect2, varscan2
- KIF20B | c.3070A>G p.T1024A (on ENST00000371728 / NM_001284259.2; = p.T984A on NM_016195.4) | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.97); catalogued as COSV53312571; called by muse, mutect2, varscan2
- KIR2DL4 | c.350T>C p.F117S (on ENST00000396284; = p.F78S on NM_001080770.2) | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.979); catalogued as rs1429498421, COSV100610466; called by muse, mutect2, varscan2
- KIR3DL2 | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV54394255; called by muse, mutect2, varscan2
- KLHL1 | c.1556C>A p.T519K | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375869705, COSV64778359; called by muse, mutect2, varscan2
- KLHL7 | c.1687G>T p.A563S (on ENST00000339077 / NM_001031710.3; = p.A515S on NM_018846.5) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV59163527; called by muse, mutect2, varscan2
- KRT73 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV59841001; called by muse, mutect2, varscan2
- KRT84 | c.1126A>T p.N376Y | Missense Mutation (SNP) | VAF 116/177 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV57772990; called by muse, mutect2, varscan2
- KRTAP9-4 | c.144C>A p.C48* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV61897331; called by muse, mutect2, varscan2
- L3MBTL1 | c.1116G>T p.W372C (on ENST00000418998 / NM_001377303.1; = p.W282C on NM_015478.7) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64229333; called by muse, mutect2, varscan2
- LAMA1 | c.2977G>T p.G993C | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67541513; called by muse, mutect2, varscan2
- LARGE1 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.082); catalogued as COSV61667924; called by muse, mutect2, varscan2
- LCE1C | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.654); catalogued as rs534849272, COSV64218993; called by muse, mutect2, varscan2
- LCLAT1 | c.1193G>A p.C398Y | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.645); catalogued as rs1196698217, COSV58376536; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV53276741, COSV53283364; called by muse, mutect2, varscan2
- LIX1L | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63417221; called by muse, mutect2, varscan2
- LMO2 | c.206G>T p.R69L (on ENST00000395833 / NM_001142315.2; = p.R138L on NM_005574.4) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV57647021; called by muse, mutect2, varscan2
- LRCH3 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1255063333, COSV58395142; called by muse, mutect2, varscan2
- LRP1B | c.11549T>C p.V3850A | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV67255746; called by muse, mutect2, varscan2
- LRP1B | c.9262G>T p.V3088F | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV67255749; called by muse, mutect2, varscan2
- LRRC47 | c.1147G>T p.V383F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV65563289; called by muse, mutect2, varscan2
- LRRC66 | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | catalogued as COSV58635773; called by muse, mutect2, varscan2
- LTBP1 | c.4438G>T p.G1480C (on ENST00000404816 / NM_206943.4; = p.G1154C on NM_000627.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55383212; called by muse, mutect2, varscan2
- MAGEC3 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV68924103; called by muse, mutect2, varscan2
- MAP4K4 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.921); catalogued as rs980383229, COSV56326751, COSV56336108; called by muse, mutect2, varscan2
- MATN2 | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54706499; called by muse, mutect2
- MCF2 | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV58491399; called by muse, mutect2, varscan2
- MCM6 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV51468342; called by muse, mutect2, varscan2
- MCOLN3 | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs773512436, COSV100352499, COSV62015339; called by muse, mutect2, varscan2
- MDGA2 | c.2319G>T p.L773F (on ENST00000399232 / NM_001113498.2; = p.L475F on NM_182830.4) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62107008; called by muse, mutect2, varscan2
- ME2 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58424475; called by muse, mutect2, varscan2
- MED13 | c.6154C>A p.H2052N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.686); catalogued as COSV67265850, COSV67267635; called by muse, mutect2, varscan2
- METAP1 | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56445383; called by muse, mutect2, varscan2
- MINDY4 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs762499754, COSV54676999; called by muse, mutect2, varscan2
- MMP11 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53157383; called by muse, mutect2, varscan2
- MMP16 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs772275333, COSV54173568, COSV54192724; called by muse, mutect2, varscan2
- MN1 | c.2942C>G p.A981G | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100179593; called by muse, mutect2, varscan2
- MN1 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV56560748; called by muse, mutect2, varscan2
- MPEG1 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 99/127 reads (78%) | catalogued as COSV57093529; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56622996; called by muse, mutect2, varscan2
- MROH2B | c.4195G>T p.E1399* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV68187515; called by muse, mutect2
- MRPL4 | c.784A>T p.T262S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.774); catalogued as COSV53449325; called by mutect2, varscan2
- MUC16 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV67481892; called by muse, mutect2, varscan2
- MXRA5 | c.6892A>C p.T2298P | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV54244398; called by muse, mutect2, varscan2
- MYB | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1294474255, COSV57200551; called by muse, mutect2, varscan2
- MYF5 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57355972; called by muse, mutect2, varscan2
- MYH11 | c.719C>A p.S240* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV55563837; called by muse, mutect2, varscan2
- MYH8 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV67965747; called by muse, mutect2, varscan2
- MYO18B | c.3179C>A p.A1060D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as COSV59143329; called by muse, mutect2, varscan2
- MYO9A | c.6343A>T p.T2115S | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV61855041; called by muse, mutect2, varscan2
- MYO9A | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446777370, COSV61855049; called by muse, mutect2, varscan2
- MYOF | c.2663T>G p.V888G | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV63708360; called by muse, mutect2, varscan2
- MYPN | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62736883; called by muse, mutect2, varscan2
- NACA2 | c.206A>C p.Q69P | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV71713154, COSV71713180; called by muse, mutect2, varscan2
- NARS1 | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.53); catalogued as COSV56877820; called by muse, mutect2, varscan2
- NAV3 | c.6230C>T p.S2077F (on ENST00000397909 / NM_001024383.2; = p.S2055F on NM_014903.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs779055385, COSV57101313; called by muse, mutect2, varscan2
- NAV3 | c.6662G>T p.W2221L (on ENST00000397909 / NM_001024383.2; = p.W2199L on NM_014903.6) | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57101324; called by muse, mutect2, varscan2
- NBR1 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as COSV57834538; called by muse, mutect2
- NCKAP1 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV62942606; called by muse, mutect2, varscan2
- NEB | c.5161G>T p.E1721* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV51419215, COSV51443067; called by muse, mutect2, varscan2
- NEB | c.4858G>T p.A1620S | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV51443104; called by muse, mutect2, varscan2
- NETO1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55001858, COSV55012005; called by muse, mutect2, varscan2
- NFX1 | c.2331G>T p.E777D | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59312059; called by muse, mutect2, varscan2
- NIBAN2 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 55/70 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV64825150; called by muse, mutect2, varscan2
- NIPBL | c.3969G>T p.M1323I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56960696; called by muse, mutect2, varscan2
- NLGN1 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759920861, COSV64342305; called by muse, mutect2, varscan2
- NLGN4X | c.1358C>A p.A453D | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52030038, COSV99323074; called by muse, mutect2, varscan2
- NLRP11 | c.739A>T p.S247C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64088371; called by muse, mutect2, varscan2
- NLRP11 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV64088373; called by muse, mutect2, varscan2
- NLRP4 | c.2263T>A p.Y755N | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV56719836; called by muse, mutect2, varscan2
- NLRP8 | c.2857T>A p.C953S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.222); catalogued as COSV52591643; called by muse, mutect2, varscan2
- NOS1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.018); catalogued as COSV57607786; called by muse, mutect2, varscan2
- NOS2 | c.2293C>A p.L765M | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV58226242; called by muse, mutect2, varscan2
- NPHS1 | c.2296A>T p.N766Y | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62289271; called by muse, mutect2, varscan2
- NPY5R | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 81/127 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV58453194; called by muse, mutect2, varscan2
- NR5A2 | c.1099A>T p.R367* (on ENST00000367362 / NM_205860.3; = p.R321* on NM_003822.5) | Nonsense Mutation (SNP) | VAF 37/105 reads (35%) | catalogued as COSV52655078; called by muse, mutect2, varscan2
- NRK | c.4263A>T p.K1421N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54602889; called by muse, mutect2, varscan2
- NRROS | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs866758642, COSV60746637; called by muse, mutect2, varscan2
- NRROS | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100145294; called by muse, mutect2, varscan2
- NRXN1 | c.4391C>A p.S1464Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60513495, COSV60515579; called by muse, mutect2, varscan2
- NRXN3 | c.2229del p.K744Sfs*6 (on ENST00000335750 / NM_001330195.2; = p.K371Sfs*6 on NM_004796.6) | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | catalogued as COSV59718733; called by mutect2, pindel, varscan2
- NTS | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as rs141571076; called by muse, mutect2, varscan2
- NXPH2 | c.179T>A p.V60D | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV55645444; called by muse, mutect2, varscan2
- OBSL1 | c.3718G>C p.A1240P | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV54709105; called by muse, mutect2
- OR13C9 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52243167; called by muse, mutect2, varscan2
- OR1D2 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV58922139; called by muse, mutect2, varscan2
- OR1E1 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59459455; called by muse, mutect2, varscan2
- OR2J2 | c.171C>A p.H57Q | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV65848266; called by muse, mutect2, varscan2
- OR2L13 | c.575G>T p.W192L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.587); catalogued as COSV100813626, COSV63561471; called by muse, mutect2, varscan2
- OR2T2 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100737633, COSV61618684; called by muse, mutect2, varscan2
- OR2T8 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100178177, COSV60664030; called by muse, mutect2, varscan2
- OR4F17 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100535514; called by mutect2, varscan2
- OR51B5 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV56176884; called by muse, mutect2, varscan2
- OR52A5 | c.307A>T p.M103L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as COSV56616136; called by muse, mutect2, varscan2
- OR52B4 | c.604T>A p.F202I | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs1473178061, COSV68769331; called by muse, mutect2, varscan2
- OR52N1 | c.402T>A p.Y134* | Nonsense Mutation (SNP) | VAF 45/56 reads (80%) | catalogued as COSV57693807; called by muse, mutect2, varscan2
- OR56A1 | c.177C>A p.H59Q | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV57363466; called by muse, mutect2, varscan2
- OR56A4 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.925); catalogued as COSV58111276; called by muse, mutect2, varscan2
- OR5H2 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV62351473; called by muse, mutect2, varscan2
- OR5H6 | c.374C>A p.T125N (on ENST00000642105; = p.T109N on NM_001005479.2) | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs938876985, COSV101051727; called by muse, varscan2
- OR5K1 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60304962; called by muse, mutect2, varscan2
- OR5L2 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 125/159 reads (79%) | catalogued as COSV65724725; called by muse, mutect2, varscan2
- OR5P3 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60429684; called by muse, mutect2, varscan2
- OR8H3 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 91/122 reads (75%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs1400753248, COSV57910448; called by muse, mutect2, varscan2
- OR8K3 | c.618T>A p.D206E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV57132420; called by muse, mutect2
- ORC2 | c.830G>T p.S277I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); catalogued as COSV52238572, COSV52240572; called by muse, mutect2
- OSBPL9 | c.687G>T p.L229F | Missense Mutation (SNP) | VAF 67/86 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV61873232; called by muse, mutect2, varscan2
- OTOP1 | c.326G>T p.W109L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV56395622; called by muse, mutect2, varscan2
- PAK5 | c.1675C>A p.L559I | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62020347, COSV62034140; called by muse, mutect2, varscan2
- PAX4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV58390307; called by muse, mutect2, varscan2
- PCDH11X | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV53491595; called by muse, mutect2, varscan2
- PCDH7 | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62341757, COSV62344417; called by muse, mutect2, varscan2
- PCDHA11 | c.1001C>A p.T334K | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.046); catalogued as COSV56532167; called by muse, mutect2, varscan2
- PCDHAC2 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV53862996; called by muse, mutect2, varscan2
- PCDHB11 | c.834C>G p.C278W | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV53382006, COSV99504795; called by muse, mutect2, varscan2
- PCDHB4 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV52025275; called by muse, mutect2, varscan2
- PCDHGA6 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV53997691, COSV54001422; called by muse, mutect2, varscan2
- PCDHGA8 | c.1030A>T p.R344* | Nonsense Mutation (SNP) | VAF 79/103 reads (77%) | catalogued as COSV54001437; called by muse, mutect2, varscan2
- PCLO | c.6712G>T p.D2238Y | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV61654908; called by muse, mutect2, varscan2
- PDCL3 | c.369-2A>G p.X123_splice | Splice Site (SNP) | VAF 18/55 reads (33%) | catalogued as rs758431306, COSV51809959; called by muse, mutect2, varscan2
- PDE3A | c.1379G>T p.R460I | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV62979479; called by muse, mutect2, varscan2
- PDILT | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56703873; called by muse, mutect2, varscan2
- PEG3 | c.2257A>T p.S753C | Missense Mutation (SNP) | VAF 92/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55642388; called by muse, mutect2, varscan2
- PELI2 | c.1017G>T p.R339S | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV50714055; called by muse, mutect2, varscan2
- PHF13 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV50010972, COSV50011407; called by muse, mutect2, varscan2
- PHF2 | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV63682877; called by muse, mutect2, varscan2
- PIBF1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs141453174, COSV58326640; called by muse, mutect2, varscan2
- PIH1D1 | c.524C>A p.S175* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV51808153; called by muse, mutect2, varscan2
- PIK3C2B | c.1597G>T p.V533F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV65813394; called by muse, mutect2, varscan2
- PIK3C2G | c.3861C>A p.H1287Q (on ENST00000676171; = p.H1246Q on NM_004570.5) | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56823822; called by muse, mutect2, varscan2
- PIK3CB | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1485169490, COSV56688472; called by muse, mutect2, varscan2
- PIKFYVE | c.2191-2A>T p.X731_splice | Splice Site (SNP) | VAF 36/75 reads (48%) | catalogued as COSV52246411; called by muse, mutect2, varscan2
- PIWIL2 | c.1417A>G p.I473V | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as COSV63253186; called by muse, mutect2, varscan2
- PLAG1 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 63/223 reads (28%) | catalogued as COSV57609638; called by muse, mutect2, varscan2
- PLEKHG1 | c.2471A>T p.H824L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV62049852; called by muse, mutect2
- PLOD1 | c.1657C>G p.P553A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52148565; called by muse, mutect2, varscan2
- PMCH | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV59675474; called by muse, mutect2, varscan2
- PNPLA6 | c.2340C>A p.S780R (on ENST00000414982 / NM_001166111.2; = p.S732R on NM_006702.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV55382779, COSV99654320; called by muse, mutect2, varscan2
- POGLUT1 | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55157811; called by muse, mutect2, varscan2
- POTEE | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58239024; called by muse, varscan2
- POTEF | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV62543034; called by muse, varscan2
- POTEF | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV62543040; called by muse, mutect2
- PPM1L | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV72263328; called by muse, mutect2, varscan2
- PRAMEF19 | c.1147T>C p.C383R | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV65818917; called by muse, mutect2
- PREX2 | c.1569G>A p.Q523= | Splice Region (SNP) | VAF 20/75 reads (27%) | catalogued as COSV55790736; called by muse, mutect2, varscan2
- PRG4 | c.3152C>T p.T1051I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV63356139; called by muse, mutect2, varscan2
- PRKCG | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 198/395 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54730990, COSV99668425; called by muse, mutect2, varscan2
- PRKDC | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1384978879, COSV58059704; called by muse, mutect2, varscan2
- PRODH2 | c.655C>T p.R219W (on ENST00000301175; = p.R143W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs780775017, COSV56561175; called by muse, mutect2, varscan2
- PROKR2 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV54087934; called by muse, mutect2, varscan2
- PROSER1 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768439864, COSV61488963; called by muse, mutect2, varscan2
- PRPF4B | c.2423G>A p.R808K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.973); catalogued as COSV61785179; called by muse, mutect2, varscan2
- PRRC2B | c.4294A>C p.S1432R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV61941289; called by muse, mutect2
- PSG4 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 136/319 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as COSV54938677; called by muse, mutect2, varscan2
- PSG6 | c.646T>A p.C216S | Missense Mutation (SNP) | VAF 199/231 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51835910; called by muse, mutect2, varscan2
- PTOV1 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55589463; called by muse, mutect2, varscan2
- PTPN18 | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51560139; called by muse, mutect2, varscan2
- PTPRT | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62005290; called by muse, mutect2, varscan2
- PYDC2 | c.183C>G p.S61R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV72921408; called by muse, mutect2, varscan2
- PYGL | c.524G>T p.W175L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.38); catalogued as COSV53587710; called by muse, mutect2, varscan2
- PZP | c.1227T>A p.S409R | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV54367005; called by muse, mutect2, varscan2
- QRICH2 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as rs1036178655, COSV53156372; called by muse, mutect2
- RAB7A | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54043411; called by muse, mutect2, varscan2
- RABL3 | c.534+1G>T p.X178_splice | Splice Site (SNP) | VAF 81/228 reads (36%) | catalogued as COSV56337277; called by muse, mutect2, varscan2
- RALGAPA1 | c.5944G>A p.A1982T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51891911; called by muse, mutect2, varscan2
- RASGRP3 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67821888, COSV67824085; called by muse, mutect2, varscan2
- RBM42 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV52898699; called by muse, mutect2, varscan2
- RBM45 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV53721987; called by muse, mutect2, varscan2
- RCBTB1 | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51636030; called by muse, mutect2, varscan2
- REG3G | c.438T>A p.C146* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV55450957; called by muse, mutect2, varscan2
- RFX7 | c.2296G>T p.E766* (on ENST00000559447 / NM_001368074.1; = p.E863* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV57966969; called by mutect2, varscan2
- RIMS2 | c.1521G>A p.M507I (on ENST00000666250 / NM_001348490.2; = p.M315I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV51707941; called by muse, mutect2, varscan2
- RNF126 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV52779107; called by muse, mutect2, varscan2
- RNF17 | c.4493C>A p.A1498E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55047101; called by muse, mutect2, varscan2
- RNF31 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV60727903; called by muse, mutect2, varscan2
- ROBO1 | c.4235A>T p.E1412V | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV71397177; called by muse, mutect2, varscan2
- ROBO3 | c.1942C>A p.R648S | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs367653125, COSV67302053; called by muse, mutect2, varscan2
- ROS1 | c.4375G>A p.A1459T | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63852809; called by muse, mutect2, varscan2
- RP1L1 | c.4555G>A p.V1519M | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66758504; called by muse, mutect2, varscan2
- RRN3 | c.1946G>T p.S649I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.055); catalogued as COSV52216124; called by muse, mutect2, varscan2
- RTL1 | c.3715G>C p.D1239H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV66017479; called by muse, varscan2
- RTL3 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV58185147; called by muse, mutect2, varscan2
- RTN3 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as rs769268946, COSV58030825; called by muse, mutect2, varscan2
- RUBCNL | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV59792347; called by muse, mutect2, varscan2
- RYR1 | c.2902C>A p.P968T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62105406; called by muse, mutect2, varscan2
- RYR2 | c.4271C>A p.S1424Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV63703505; called by muse, mutect2, varscan2
- RYR2 | c.7866C>A p.C2622* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV63703515; called by muse, mutect2, varscan2
- RYR3 | c.3008G>T p.W1003L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66802979, COSV66808108; called by muse, mutect2, varscan2
- RYR3 | c.6585C>A p.Y2195* | Nonsense Mutation (SNP) | VAF 13/17 reads (76%) | catalogued as COSV66802985; called by muse, mutect2, varscan2
- S100A8 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64198174; called by muse, mutect2, varscan2
- SALL3 | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV73305858, COSV73306316; called by muse, mutect2
- SAMD9L | c.2166A>G p.I722M | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59083885; called by muse, mutect2, varscan2
- SCN1A | c.5682G>T p.M1894I (on ENST00000303395 / NM_001202435.3; = p.M1883I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV57681015; called by muse, mutect2, varscan2
- SCN2A | c.49T>A p.F17I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV51850438; called by muse, mutect2
- SCN8A | c.5653C>A p.P1885T | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61988933; called by muse, mutect2, varscan2
- SCN8A | c.5879G>C p.R1960P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.225); catalogued as COSV61989024; called by muse, mutect2, varscan2
- SEC16B | c.2257G>T p.G753W | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.715); catalogued as COSV57628643; called by muse, mutect2, varscan2
- SEPTIN14 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217236080, COSV66425797, COSV66429804; called by muse, mutect2, varscan2
- SEPTIN14 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66429815; called by muse, mutect2, varscan2
- SEPTIN7 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as COSV63256170; called by muse, mutect2, varscan2
- SERPINA12 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57945417; called by muse, mutect2, varscan2
- SERPINB12 | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54034426; called by muse, mutect2, varscan2
- SERPINH1 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.28); PolyPhen benign (0.326); catalogued as COSV63998347; called by muse, mutect2, varscan2
- SESN3 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV53585875, COSV99565902; called by muse, mutect2, varscan2
- SETBP1 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56331481; called by muse, mutect2, varscan2
- SETBP1 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56331498, COSV56336472; called by muse, mutect2, varscan2
- SETD5 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56715347; called by muse, mutect2, varscan2
- SGSH | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs760096011, CM128247, COSV58340064; called by muse, mutect2, varscan2
- SH2D5 | c.491C>G p.T164R (on ENST00000444387 / NM_001103161.2; = p.T80R on NM_001103160.2) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as rs752464656, COSV66707263; called by muse, mutect2, varscan2
- SH3GL3 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61059760, COSV61062546; called by muse, mutect2, varscan2
- SH3KBP1 | c.1385-1G>A p.X462_splice | Splice Site (SNP) | VAF 23/28 reads (82%) | catalogued as COSV65648890; called by muse, mutect2, varscan2
- SIRPB2 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV63124800; called by muse, mutect2, varscan2
- SIRT2 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50876215; called by muse, mutect2, varscan2
- SLC12A3 | c.823T>C p.S275P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52637622; called by muse, mutect2, varscan2
- SLC17A2 | c.1283C>A p.T428N (on ENST00000265425; = p.L379M on NM_005835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV55353051; called by muse, mutect2, varscan2
- SLC17A6 | c.902C>A p.T301N | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV54139393; called by muse, mutect2, varscan2
- SLC17A6 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 28/33 reads (85%) | catalogued as rs527723180, COSV54139403; called by muse, mutect2, varscan2
- SLC18B1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs367822370; called by muse, mutect2, varscan2
- SLC39A6 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV52370559; called by muse, mutect2, varscan2
- SLC5A8 | c.1644G>T p.Q548H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV73310992; called by muse, mutect2, varscan2
- SLC6A2 | c.1567T>C p.F523L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.246); catalogued as COSV54920891; called by muse, mutect2, varscan2
- SLC7A6OS | c.599T>G p.I200S | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50450475; called by muse, mutect2, varscan2
- SLC9A4 | c.362C>A p.S121* | Nonsense Mutation (SNP) | VAF 35/57 reads (61%) | catalogued as rs373107542; called by muse, mutect2, varscan2
- SLIT3 | c.1079+1G>T p.X360_splice | Splice Site (SNP) | VAF 6/11 reads (55%) | catalogued as COSV60625532; called by muse, mutect2, varscan2
- SMG5 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV62436854; called by muse, mutect2, varscan2
- SMOX | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53866989; called by muse, mutect2, varscan2
- SON | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV51666612; called by muse, mutect2, varscan2
- SORCS3 | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.308); catalogued as COSV63794518, COSV63795008; called by muse, mutect2, varscan2
- SOS2 | c.3137G>A p.G1046D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.072); catalogued as COSV53571839; called by muse, mutect2, varscan2
- SOX14 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV60163272; called by muse, mutect2, varscan2
- SPAG16 | c.1721-1G>T p.X574_splice | Splice Site (SNP) | VAF 32/66 reads (48%) | catalogued as rs992136031, COSV56975930; called by muse, mutect2
- SPATA2 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56867705; called by muse, mutect2, varscan2
- SPATA31E1 | c.2260A>G p.R754G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV57794003; called by muse, mutect2, varscan2
- SPATA31E1 | c.2499G>T p.Q833H | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as COSV57794009; called by muse, mutect2, varscan2
- SPATA31E1 | c.3143C>A p.T1048N | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.487); catalogued as COSV57794015; called by muse, mutect2, varscan2
- SPEN | c.6673G>A p.D2225N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV65364233, COSV65365798; called by muse, mutect2, varscan2
- SPOPL | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV54515218; called by muse, mutect2, varscan2
- SPRED3 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs369044035; called by muse, mutect2, varscan2
- SPTA1 | c.4390G>T p.E1464* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV63757318; called by muse, mutect2, varscan2
- SRFBP1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59584082; called by muse, mutect2, varscan2
- SRPX | c.1385G>T p.C462F | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59440495; called by muse, mutect2, varscan2
- SSH2 | c.3481G>T p.E1161* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV52177845; called by muse, varscan2
- SSH2 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52177857; called by muse, varscan2
- SSPN | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54381868; called by muse, mutect2, varscan2
- ST3GAL1 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | PolyPhen benign (0.049); catalogued as COSV60615428; called by muse, mutect2, varscan2
- ST8SIA3 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 35/72 reads (49%) | PolyPhen probably damaging (1); catalogued as COSV60654879; called by muse, mutect2, varscan2
- ST8SIA3 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 23/32 reads (72%) | PolyPhen possibly damaging (0.828); catalogued as COSV60654886; called by muse, mutect2, varscan2
- STARD13 | c.638G>T p.G213V (on ENST00000336934 / NM_001243476.3; = p.G95V on NM_052851.3) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV55234795; called by muse, mutect2, varscan2
- STK10 | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs201304022, COSV51577220; called by muse, mutect2, varscan2
- STK38 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 138/196 reads (70%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.625); catalogued as COSV57710107; called by muse, mutect2, varscan2
- STKLD1 | c.670A>C p.I224L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as COSV64314062; called by muse, mutect2, varscan2
- STRA6 | c.1256G>T p.C419F | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100120879, COSV60587746; called by muse, mutect2, varscan2
- STYXL2 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV54808374; called by muse, mutect2, varscan2
- SUGP2 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1338829278, COSV58262794; called by muse, mutect2, varscan2
- SULT1B1 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 88/116 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60208792; called by muse, mutect2, varscan2
- SYT13 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV50075503; called by muse, mutect2, varscan2
- TAF1L | c.4564G>T p.D1522Y | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54266298; called by muse, mutect2, varscan2
- TAF2 | c.812C>G p.P271R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1290059635, COSV65419902; called by muse, mutect2, varscan2
- TANC2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs773996052, COSV67338883; called by muse, mutect2, varscan2
- TAOK2 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54239314; called by muse, mutect2, varscan2
- TAS2R39 | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71470965; called by muse, mutect2, varscan2
- TAS2R9 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV53690157; called by muse, mutect2, varscan2
- TCHH | c.4184A>G p.E1395G | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV64276726; called by muse, mutect2, varscan2
- TCHH | c.1671G>T p.R557S | Missense Mutation (SNP) | VAF 63/176 reads (36%) | PolyPhen benign (0.134); catalogued as rs888337173, COSV64276731; called by muse, mutect2, varscan2
- TDG | c.680C>A p.A227E | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57167866; called by muse, mutect2, varscan2
- TEF | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.584); catalogued as COSV56748549; called by muse, mutect2, varscan2
- TET1 | c.4513C>T p.R1505C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65387723; called by muse, mutect2
- TEX15 | c.4294A>C p.S1432R (on ENST00000256246; = p.S1815R on NM_001350162.2) | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV56350696; called by muse, mutect2, varscan2
- TFIP11 | c.96G>C p.Q32H | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV68021242; called by muse, mutect2, varscan2
- TG | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV55088639; called by muse, mutect2
- THNSL2 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV59084123; called by muse, mutect2, varscan2
- THSD7B | c.3169A>T p.S1057C (on ENST00000272643; = p.S1055C on NM_001316349.2) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55719706; called by muse, mutect2, varscan2
- TLE1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs1354697064, COSV64686531; called by muse, mutect2, varscan2
- TMEM41A | c.760A>T p.T254S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV53988282; called by muse, mutect2, varscan2
- TMEM79 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV55296678, COSV55297587; called by muse, mutect2, varscan2
- TMPRSS11B | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60293451; called by muse, mutect2, varscan2
- TMTC3 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.075); catalogued as COSV57125487, COSV99897927; called by muse, varscan2
- TNC | c.2019C>G p.D673E | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV60788484; called by muse, mutect2, varscan2
- TNNT3 | c.508G>C p.A170P (on ENST00000397301 / NM_001367846.1; = p.A159P on NM_006757.4) | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.718); catalogued as COSV53488532; called by muse, mutect2, varscan2
- TOPBP1 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as rs1051739315, COSV53439798; called by muse, mutect2, varscan2
- TPR | c.4516G>A p.E1506K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV66603670; called by muse, mutect2, varscan2
- TPTE2 | c.874C>A p.P292T (on ENST00000400230 / NM_199254.2; = p.P215T on NM_130785.3) | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55025734; called by muse, mutect2, varscan2
- TRAK2 | c.1410G>T p.K470N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV60273934; called by muse, mutect2, varscan2
- TRIM2 | c.1261G>A p.V421M (on ENST00000437508; = p.V448M on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1259239193, COSV58637154; called by muse, mutect2, varscan2
- TRIM58 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV63571591; called by muse, mutect2, varscan2
- TRIML1 | c.759G>T p.R253S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60194332, COSV60196016; called by muse, mutect2, varscan2
- TRIP11 | c.3385A>G p.K1129E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV50944483; called by muse, mutect2, varscan2
- TROAP | c.1113G>T p.W371C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV57745347; called by muse, mutect2, varscan2
- TRPC7 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as rs551264578, COSV61461425; called by muse, mutect2, varscan2
- TRPS1 | c.383C>T p.P128L (on ENST00000220888 / NM_001330599.2; = p.P141L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs201699015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPAN10 | c.523G>T p.A175S (on ENST00000574882 / NM_001290212.1; = p.A137S on NM_031945.4) | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.55); catalogued as COSV60773710; called by muse, mutect2
- TTN | c.58258C>A p.P19420T (on ENST00000591111; = p.P11996T on NM_003319.4) | Missense Mutation (SNP) | VAF 60/158 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV60238797; called by muse, mutect2, varscan2
- TTN | c.15005A>G p.K5002R (on ENST00000591111; = p.K4075R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | PolyPhen possibly damaging (0.894); catalogued as rs779733584, COSV60238842; called by muse, mutect2, varscan2
- TUBGCP2 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53307561; called by muse, mutect2
- UAP1 | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV54852665; called by muse, mutect2, varscan2
- UBA3 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62741117; called by muse, mutect2, varscan2
- UBE2E2 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV59975651; called by muse, mutect2, varscan2
- UBE2T | c.385-2A>T p.X129_splice | Splice Site (SNP) | VAF 40/87 reads (46%) | catalogued as COSV66153590; called by muse, mutect2, varscan2
- UGGT1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52139601; called by muse, mutect2, varscan2
- UGT2A2 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV99683638; called by muse, mutect2, varscan2
- UGT8 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.784); catalogued as COSV60419744; called by muse, mutect2, varscan2
- UGT8 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.784); catalogued as COSV60417752; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3269G>T p.C1090F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV54440839; called by muse, mutect2, varscan2
- UNC45B | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV52098982; called by muse, mutect2, varscan2
- UNC5D | c.1240G>T p.V414F | Missense Mutation (SNP) | VAF 114/146 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54820228; called by muse, mutect2, varscan2
- UPF2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 58/66 reads (88%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV62662599; called by muse, mutect2, varscan2
- UROC1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as rs754495263, COSV52037035; called by muse, mutect2, varscan2
- USP34 | c.4454G>T p.S1485I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1294028253, COSV68404369; called by muse, mutect2, varscan2
- USP36 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1427812221, COSV61753205; called by muse, mutect2
- UTP25 | c.529A>T p.S177C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as COSV72227481; called by muse, mutect2, varscan2
- VCAN | c.3908G>T p.G1303V | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV54112657; called by muse, mutect2, varscan2
- VCAN | c.9575C>A p.A3192E | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54112665; called by muse, mutect2
- VPS13B | c.5203G>C p.D1735H | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62152142; called by muse, mutect2, varscan2
- VPS13B | c.8765A>T p.K2922M | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62142507; called by muse, mutect2, varscan2
- VWA3B | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68245363; called by muse, mutect2, varscan2
- WASL | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.76); catalogued as COSV56135291; called by muse, mutect2, varscan2
- WDR45B | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66408989; called by muse, mutect2, varscan2
- WDR72 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64751604; called by muse, mutect2, varscan2
- WNT10B | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs754912151, COSV56406050; called by muse, mutect2, varscan2
- WRAP53 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs762178428, COSV56834452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XDH | c.1796G>C p.R599P | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV65150437; called by muse, mutect2, varscan2
- YWHAB | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62304662; called by muse, mutect2, varscan2
- ZC3H12B | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 41/54 reads (76%) | catalogued as COSV59050456; called by muse, mutect2, varscan2
- ZEB2 | c.1462G>A p.G488S | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.04); catalogued as rs1392383826, COSV57962569; called by muse, mutect2, varscan2
- ZFYVE16 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62016800; called by muse, mutect2
- ZIC4 | c.865G>T p.G289W | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs767796917, COSV67173333, COSV67173350; called by muse, mutect2, varscan2
- ZMYND8 | c.1420G>T p.A474S (on ENST00000311275 / NM_001363741.2; = p.A494S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV53692412; called by muse, mutect2, varscan2
- ZNF135 | c.461C>A p.T154K (on ENST00000313434 / NM_001289401.2; = p.T166K on NM_003436.4) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV57881402, COSV57884583; called by muse, mutect2, varscan2
- ZNF197 | c.2917C>G p.L973V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV56077178; called by muse, mutect2, varscan2
- ZNF257 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs376879531; called by muse, mutect2, varscan2
- ZNF274 | c.1710G>T p.R570S (on ENST00000610905; = p.R465S on NM_016324.3) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV58765925; called by muse, mutect2, varscan2
- ZNF300 | c.1279C>A p.H427N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51042800; called by muse, mutect2, varscan2
- ZNF33A | c.1918G>T p.E640* (on ENST00000458705 / NM_006974.3; = p.E641* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 41/66 reads (62%) | catalogued as COSV56724847, COSV56726931; called by muse, mutect2, varscan2
- ZNF385C | c.1120T>A p.C374S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56918275; called by muse, mutect2, varscan2
- ZNF407 | c.2823G>A p.M941I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55263794; called by muse, mutect2, varscan2
- ZNF473 | c.859A>T p.T287S | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV54522072; called by muse, mutect2, varscan2
- ZNF479 | c.262G>C p.V88L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV58641855; called by muse, mutect2, varscan2
- ZNF536 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs752138319, COSV62819827; called by muse, mutect2, varscan2
- ZNF552 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.562); catalogued as COSV101197498; called by muse, mutect2, varscan2
- ZNF569 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV57597889; called by muse, mutect2, varscan2
- ZNF579 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV57638424, COSV57638602; called by muse, mutect2, varscan2
- ZNF616 | c.856G>T p.V286F | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs1431934932, COSV57512619; called by muse, mutect2, varscan2
- ZNF687 | c.3284C>T p.P1095L | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs376641944; called by muse, mutect2, varscan2
- ZNF761 | c.1600A>T p.K534* | Nonsense Mutation (SNP) | VAF 62/160 reads (39%) | catalogued as COSV61888711, COSV61889037; called by muse, mutect2
- ZSCAN21 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 105/144 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs753507645, COSV52850907, COSV52851854; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2788_2805del p.L930_C935del | In Frame Del (DEL) | VAF 15/113 reads (13%) | called by mutect2, pindel
- CC2D1B | c.210del p.Q71Rfs*36 | Frame Shift Del (DEL) | VAF 86/166 reads (52%) | called by mutect2, pindel, varscan2
- CEP128 | c.2500del p.E834Kfs*17 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | called by mutect2, pindel, varscan2
- DHX34 | c.49dup p.R17Pfs*30 | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- EFR3A | c.2343del p.L782Wfs*15 | Frame Shift Del (DEL) | VAF 50/120 reads (42%) | called by mutect2, pindel, varscan2
- FBN2 | c.1984_1985insC p.C662Sfs*16 | Frame Shift Ins (INS) | VAF 23/42 reads (55%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.340T>G p.Y114D | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV3-11 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV1D-17 | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ISM1 | c.482_483insT p.W161Cfs*47 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- MAGEC3 | c.713del p.G238Afs*4 | Frame Shift Del (DEL) | VAF 70/115 reads (61%) | called by mutect2, pindel, varscan2
- MAML2 | c.1508del p.G503Afs*7 | Frame Shift Del (DEL) | VAF 29/50 reads (58%) | called by mutect2, pindel, varscan2
- MROH5 | c.1999del p.H667Tfs*69 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | called by mutect2, pindel, varscan2
- MUC17 | c.4198dup p.S1400Kfs*13 | Frame Shift Ins (INS) | VAF 100/199 reads (50%) | called by mutect2, pindel, varscan2
- NLRP13 | c.840del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- NRCAM | c.626del p.P209Qfs*28 (on ENST00000379028 / NM_001371124.1; = p.P203Qfs*28 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 63/121 reads (52%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.92del p.K31Rfs*10 | Frame Shift Del (DEL) | VAF 35/129 reads (27%) | called by mutect2, pindel, varscan2
- PRAMEF1 | c.113del p.P38Hfs*15 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | called by mutect2, varscan2
- PRAMEF18 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PRAMEF20 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- REV3L | c.3031dup p.M1011Nfs*5 | Frame Shift Ins (INS) | VAF 25/96 reads (26%) | called by mutect2, pindel, varscan2
- RNF148 | c.189del p.N64Ifs*26 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- RP1L1 | c.1081del p.E361Rfs*2 | Frame Shift Del (DEL) | VAF 51/84 reads (61%) | called by mutect2, pindel, varscan2
- SBSN | c.1464del p.K489Rfs*57 (on ENST00000452271 / NM_001166034.2; = p.K146Rfs*57 on NM_198538.4) | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | called by mutect2, pindel, varscan2
- SLC22A7 | c.972del p.E326Nfs*10 (on ENST00000372585 / NM_153320.2; = p.E324Nfs*10 on NM_006672.3) | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel
- SPATA31A1 | c.1795C>A p.L599M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by mutect2, varscan2
- SRCIN1 | c.3080C>G p.P1027R (on ENST00000621492; = p.P993R on NM_025248.3) | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRBV19 | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 60/77 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TRBV2 | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 42/62 reads (68%) | called by muse, varscan2
- TTLL1 | c.265del p.E89Rfs*36 | Frame Shift Del (DEL) | VAF 39/92 reads (42%) | called by pindel, varscan2
- TTN | c.96097del p.R32033Dfs*35 (on ENST00000591111; = p.R24609Dfs*35 on NM_003319.4) | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- ZNF488 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF492 | c.703A>C p.N235H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by mutect2, varscan2
- A2M | c.2707C>T p.L903= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV59390543; called by muse, mutect2, varscan2
- ACAP3 | c.894G>T p.L298= | Silent (SNP) | VAF 54/125 reads (43%) | catalogued as COSV61222963; called by muse, mutect2, varscan2
- ACSM1 | c.1365G>A p.K455= | Silent (SNP) | VAF 179/467 reads (38%) | catalogued as COSV54634546, COSV54637809; called by muse, mutect2, varscan2
- ADAMTS13 | c.1917C>G p.R639= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV63022508; called by muse, mutect2, varscan2
- ADGRG4 | c.6483T>C p.T2161= | Silent (SNP) | VAF 41/47 reads (87%) | catalogued as rs1326048109, COSV54963164; called by muse, mutect2, varscan2
- AK9 | c.1218A>T p.T406= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as COSV53422785; called by muse, mutect2, varscan2
- AKNA | c.3993G>A p.A1331= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs370740104; called by muse, mutect2, varscan2
- ALG10B | c.1092A>G p.Q364= | Silent (SNP) | VAF 73/127 reads (57%) | catalogued as COSV58144245; called by muse, mutect2, varscan2
- ANKFN1 | c.312T>A p.S104= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV59455112; called by muse, mutect2, varscan2
- ANKRD55 | c.1788C>T p.H596= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV61947059; called by muse, mutect2
- APBB1IP | c.354C>A p.A118= | Silent (SNP) | VAF 100/131 reads (76%) | catalogued as COSV63301889, COSV63303521; called by muse, varscan2
- AREL1 | c.2028G>T p.V676= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as COSV62667551; called by muse, mutect2, varscan2
- ATG2A | c.249C>T p.A83= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs374688586; called by muse, mutect2, varscan2
- CACNA1S | c.1593C>A p.R531= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV62942246; called by muse, mutect2, varscan2
- CAMK2B | c.117G>A p.E39= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs770287814, COSV51664257; called by muse, mutect2, varscan2
- CCDC136 | c.2397C>T p.A799= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV52803011; called by muse, mutect2, varscan2
- CD4 | c.1173C>T p.S391= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV50593549; called by muse, mutect2, varscan2
- CDH18 | c.2250C>T p.I750= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs867045210, COSV56946895; called by muse, mutect2, varscan2
- CDH9 | c.240C>T p.D80= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV50369356; called by muse, mutect2, varscan2
- CHD7 | c.4104A>T p.A1368= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as COSV71113275; called by muse, mutect2, varscan2
- CNTN3 | c.1269G>T p.V423= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV55180179; called by muse, mutect2, varscan2
- CNTN5 | c.1515C>T p.P505= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs769911111, COSV54340296; called by muse, mutect2, varscan2
- CPA6 | c.261C>A p.P87= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV52738236; called by muse, mutect2, varscan2
- CTDP1 | c.2226G>A p.A742= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs780699468, COSV50002548, COSV99310430; called by muse, mutect2, varscan2
- CTNNA3 | c.1758G>T p.V586= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV65608383; called by muse, mutect2, varscan2
- D2HGDH | c.240G>A p.T80= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV58322749; called by muse, mutect2
- DCHS1 | c.4818G>T p.P1606= | Silent (SNP) | VAF 42/54 reads (78%) | catalogued as COSV55040225; called by muse, mutect2, varscan2
- DDR2 | c.399G>T p.R133= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV63373019; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1590G>T p.L530= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as COSV62569764; called by muse, mutect2, varscan2
- EMC10 | c.613C>T p.L205= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV58542948; called by muse, mutect2, varscan2
- FAR1 | c.540T>C p.S180= | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as COSV61385954; called by muse, mutect2, varscan2
- FBXL13 | c.291A>G p.T97= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as COSV57542010; called by muse, mutect2, varscan2
- FEZF2 | c.525G>T p.L175= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV51864060; called by muse, mutect2, varscan2
- FKTN | c.384G>T p.R128= | Silent (SNP) | VAF 44/60 reads (73%) | catalogued as COSV56309364, COSV56311302; called by muse, mutect2, varscan2
- FLG2 | c.681T>A p.S227= | Silent (SNP) | VAF 96/272 reads (35%) | catalogued as COSV66171341; called by muse, mutect2, varscan2
- FOCAD | c.534G>T p.L178= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV58105098; called by muse, mutect2, varscan2
- GABRQ | c.831C>A p.V277= | Silent (SNP) | VAF 160/182 reads (88%) | catalogued as rs1556820001, COSV64781704, COSV64783375; called by muse, mutect2, varscan2
- GAL3ST2 | c.75C>A p.L25= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV51951184; called by muse, mutect2, varscan2
- GATA2 | c.744C>T p.T248= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV62005897; called by muse, mutect2, varscan2
- GCDH | c.1305G>T p.T435= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV53367703, COSV53368439; called by muse, mutect2, varscan2
- GPR162 | c.798C>A p.S266= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as COSV50593551; called by muse, mutect2, varscan2
- GRIN2A | c.1794T>G p.S598= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV58018335, COSV58049640; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1452G>A p.E484= | Silent (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- HAPLN3 | c.948G>A p.L316= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs191460461; called by muse, mutect2, varscan2
- HDAC7 | c.1626G>C p.P542= (on ENST00000427332; = p.P581= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV50401089; called by muse, mutect2, varscan2
- HEATR1 | c.2358G>C p.S786= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as COSV63982450; called by muse, mutect2, varscan2
- HECTD2 | c.846A>G p.Q282= | Silent (SNP) | VAF 51/70 reads (73%) | catalogued as rs767288953, COSV53223687; called by muse, mutect2, varscan2
- HEPHL1 | c.2745G>A p.K915= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as COSV59894743; called by muse, mutect2, varscan2
- HERC2 | c.3354C>T p.F1118= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs112980995; called by muse, mutect2, varscan2
- HMCN1 | c.2269T>C p.L757= | Silent (SNP) | VAF 131/264 reads (50%) | catalogued as rs1159764701, COSV54925855; called by muse, mutect2, varscan2
- HMCN1 | c.11952T>G p.V3984= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV54922853, COSV54925875; called by muse, mutect2, varscan2
- HMCN1 | c.15054G>T p.G5018= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV54925884; called by muse, mutect2, varscan2
- HSPG2 | c.11943C>T p.S3981= | Silent (SNP) | VAF 31/41 reads (76%) | catalogued as COSV60829114; called by muse, mutect2, varscan2
- IFI16 | c.1893C>G p.A631= (on ENST00000295809 / NM_001364867.2; = p.A575= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV55537997; called by muse, mutect2, varscan2
- IGHV3-15 | c.195G>A p.E65= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs1555443683; called by muse, mutect2, varscan2
- IGSF9B | c.3598C>A p.R1200= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV58070940; called by muse, mutect2, varscan2
- INHBC | c.843A>G p.P281= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV59005825; called by muse, mutect2, varscan2
- ITGA3 | c.582G>T p.T194= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV50327737; called by muse, mutect2, varscan2
- ITGA6 | c.3150G>A p.S1050= (on ENST00000442250; = p.S1011= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs373241747; called by muse, mutect2, varscan2
- KAT8 | c.325C>T p.L109= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV54898314; called by muse, mutect2, varscan2
- KLF15 | c.1161G>A p.E387= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1172693953, COSV56180765; called by muse, mutect2, varscan2
- KLRC4 | c.447G>T p.V149= | Silent (SNP) | VAF 84/289 reads (29%) | catalogued as COSV58672330; called by muse, mutect2, varscan2
- LHX2 | c.897C>G p.L299= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as rs1023798362, COSV65318876; called by muse, mutect2, varscan2
- LRRC66 | c.2370G>T p.L790= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV58635783; called by muse, mutect2, varscan2
- LRRC7 | c.261G>A p.E87= (on ENST00000651989 / NM_001370785.2; = p.E54= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs770324406, COSV50547803; called by muse, mutect2, varscan2
- LY6K | c.264T>C p.G88= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV52833305; called by muse, mutect2, varscan2
- MAGEB2 | c.618T>A p.P206= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV66781380; called by muse, mutect2, varscan2
- MANEA | c.1353A>G p.A451= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV62590277; called by muse, mutect2
- MARCHF6 | c.1008C>T p.T336= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs578040512, COSV56884837; called by muse, mutect2, varscan2
- MCEMP1 | c.207C>A p.P69= | Silent (SNP) | VAF 72/107 reads (67%) | catalogued as COSV58040665; called by muse, mutect2, varscan2
- MDGA2 | c.1878C>A p.V626= (on ENST00000399232 / NM_001113498.2; = p.V328= on NM_182830.4) | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV62107021; called by muse, mutect2, varscan2
- MIOS | c.2466C>T p.N822= | Silent (SNP) | VAF 68/129 reads (53%) | catalogued as COSV60768020; called by muse, mutect2, varscan2
- MIPOL1 | c.1245C>A p.A415= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV59389887; called by muse, mutect2, varscan2
- MLLT10 | c.1758A>G p.G586= (on ENST00000307729 / NM_001195626.3; = p.G602= on NM_004641.3) | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as COSV57001546; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1438C>T p.L480= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV56623025; called by muse, mutect2, varscan2
- MRC2 | c.480C>A p.I160= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV100316547, COSV57642799; called by muse, mutect2, varscan2
- MROH5 | c.2787C>A p.A929= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV71302378; called by muse, mutect2, varscan2
- MUC16 | c.27279C>T p.T9093= | Silent (SNP) | VAF 55/70 reads (79%) | catalogued as rs751651974, COSV67481890; called by muse, mutect2, varscan2
- MUC5B | c.13218C>A p.G4406= | Silent (SNP) | VAF 72/92 reads (78%) | catalogued as rs1163179828, COSV71594373, COSV71595261; called by muse, mutect2, varscan2
- MYH3 | c.918C>T p.T306= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as COSV56868250; called by muse, mutect2, varscan2
- MYO1H | c.513C>A p.L171= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV60449053; called by muse, mutect2, varscan2
- MYOF | c.2664C>T p.V888= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs1421511598, COSV63708350; called by muse, mutect2, varscan2
- NAV2 | c.2457C>T p.D819= (on ENST00000396087 / NM_001244963.2; = p.D796= on NM_145117.5) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs771328189, COSV62321203; called by mutect2, varscan2
- NCOA6 | c.4215G>T p.V1405= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV62866329; called by muse, mutect2, varscan2
- NDNF | c.201G>C p.V67= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV65634371; called by muse, mutect2, varscan2
- NEDD4L | c.2040C>T p.Y680= (on ENST00000400345 / NM_001144967.3; = p.Y660= on NM_015277.6) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs373128169, COSV56846772; ClinVar: likely benign; called by muse, mutect2, varscan2
- NES | c.1320C>T p.V440= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV63962244; called by muse, mutect2, varscan2
- NLGN1 | c.609G>T p.V203= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV64342299; called by muse, mutect2, varscan2
- NLRP9 | c.1707C>T p.F569= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV60463353; called by muse, mutect2, varscan2
- NOX4 | c.1371A>G p.L457= | Silent (SNP) | VAF 102/126 reads (81%) | catalogued as rs769432775, COSV54460484; called by muse, mutect2, varscan2
- NPM2 | c.84G>T p.R28= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV57075841, COSV57076292; called by muse, mutect2, varscan2
- NRG1 | c.1884G>T p.L628= (on ENST00000405005 / NM_013964.5; = p.L633= on NM_013956.5) | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV55170234; called by muse, mutect2, varscan2
- NSUN2 | c.2217A>T p.G739= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV52956103; called by muse, mutect2, varscan2
- NTRK1 | c.264G>A p.R88= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs759356484, COSV62327629; called by muse, mutect2, varscan2
- NUDT14 | c.324G>T p.V108= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV59650696; called by muse, mutect2, varscan2
- NUP210L | c.1731C>T p.T577= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as COSV55154018; called by muse, mutect2, varscan2
- OGDHL | c.2895C>A p.R965= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV65103876; called by muse, mutect2, varscan2
- OR2T34 | c.213C>A p.L71= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100170155; called by muse, mutect2, varscan2
- OR2T6 | c.417G>T p.R139= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV63216876; called by muse, mutect2, varscan2
- OR5T1 | c.768C>T p.H256= | Silent (SNP) | VAF 117/151 reads (77%) | catalogued as rs1166232091, COSV57302552, COSV57304118; called by muse, mutect2, varscan2
- ORAI1 | c.552G>A p.T184= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs782215248, COSV100345506, COSV57491885; called by muse, mutect2, varscan2
- ORC2 | c.828G>A p.L276= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV52240581, COSV99309540; called by muse, mutect2
- ORC3 | c.1290A>C p.P430= | Silent (SNP) | VAF 68/93 reads (73%) | catalogued as COSV100005461, COSV57638699; called by muse, mutect2, varscan2
- PARVG | c.699T>C p.N233= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV63562492; called by muse, mutect2, varscan2
- PCDHA9 | c.1620G>T p.A540= | Silent (SNP) | VAF 78/104 reads (75%) | catalogued as rs782367888, COSV65323524, COSV65330607; called by muse, mutect2, varscan2
- PCDHB2 | c.2322C>T p.P774= | Silent (SNP) | VAF 81/120 reads (68%) | catalogued as COSV50606193; called by muse, mutect2, varscan2
- PDZD3 | c.1395C>A p.S465= (on ENST00000531114; = p.S385= on NM_024791.4) | Silent (SNP) | VAF 83/99 reads (84%) | catalogued as COSV52707521; called by muse, mutect2, varscan2
- PGAP6 | c.1863C>T p.T621= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV51741345; called by muse, mutect2, varscan2
- PHF23 | c.354T>C p.R118= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs1186728268, COSV50035542; called by muse, mutect2, varscan2
- PHLDB2 | c.561T>C p.D187= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV67314561; called by muse, mutect2, varscan2
- PKLR | c.891C>A p.V297= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as COSV61362135; called by muse, mutect2, varscan2
- PKN1 | c.90G>T p.G30= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as COSV54401581; called by muse, mutect2, varscan2
63 further variants in this file (0 protein-altering or splice-affecting, 51 silent, 12 other) are not listed here.
